Somatic mutation profile of tumor specimen ALCH-B43W-TTP1-A (aliquot ALCH-B43W-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B43W, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.7 years (21,078 days).
Specimen ALCH-B43W-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1c09294-090c-4260-a7d7-09b6a6b9cee0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B43W-NB1-A (Blood Derived Normal), aliquot ALCH-B43W-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c1218b7-759f-4690-84c0-e2ba8d2ca740

The open-access MAF lists 71 somatic variants for this specimen: 55 protein-altering or splice-affecting, 8 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 8, Nonsense Mutation 4, Intron 3, 3'UTR 2, 5'Flank 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.72G>C p.W24C | Missense Mutation (SNP) | VAF 4/94 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960212, COSV67961561; called by muse, mutect2
- ALMS1 | c.3371C>T p.S1124L | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs369303418; called by muse, mutect2
- ARFGAP2 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99040121; called by muse, mutect2
- CAPN6 | c.1045G>T p.G349C | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as rs866039335; called by muse, mutect2
- FGFR2 | c.49A>G p.T17A | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs1417346628; called by muse, mutect2
- IL17RC | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1293715766; called by muse, mutect2, varscan2
- LETMD1 | c.121C>G p.R41G | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV50396658; called by muse, mutect2
- MAS1L | c.843C>A p.S281R | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs763183994, COSV101009717; called by muse, mutect2, varscan2
- METTL3 | c.1357G>C p.D453H | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52968360; called by muse, mutect2
- NKRF | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.025); catalogued as COSV100441370, COSV58662629; called by muse, mutect2
- NLGN1 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs780313510; called by muse, mutect2
- PEX7 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 16/484 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.578); catalogued as COSV59249440; called by muse, mutect2
- POTEM | c.401A>T p.H134L | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.432); catalogued as COSV69152822; called by muse, mutect2
- PRR14L | c.4536G>C p.K1512N | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.813); catalogued as rs1469743552, COSV57884336; called by muse, mutect2
- RPTN | c.1929G>C p.Q643H | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV60169086; called by muse, mutect2
- RYR1 | c.2924G>A p.R975Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.385); catalogued as rs778241277, COSV100616211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLITRK2 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59423756; called by muse, mutect2
- SLITRK5 | c.1466A>G p.Q489R | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV100281411; called by muse, mutect2, varscan2
- SLITRK5 | c.2007C>A p.S669R | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV61526819; called by muse, mutect2, varscan2
- TTN | c.101217G>C p.K33739N (on ENST00000591111; = p.K26315N on NM_003319.4) | Missense Mutation (SNP) | VAF 11/353 reads (3%) | PolyPhen benign (0.116); catalogued as COSV100605757; called by muse, mutect2
- TTN | c.57976C>A p.P19326T (on ENST00000591111; = p.P11902T on NM_003319.4) | Missense Mutation (SNP) | VAF 5/87 reads (6%) | PolyPhen probably damaging (0.999); catalogued as COSV60308806; called by muse, mutect2
- ZFHX4 | c.4939C>T p.Q1647* | Nonsense Mutation (SNP) | VAF 6/146 reads (4%) | catalogued as COSV99259188; called by muse, mutect2
- C3orf20 | c.1015C>G p.P339A | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.036); called by muse, mutect2
- CDON | c.2262C>G p.F754L | Missense Mutation (SNP) | VAF 12/372 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHD4 | c.2696T>A p.L899* (on ENST00000357008 / NM_001363606.2; = p.L912* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 8/129 reads (6%) | called by muse, mutect2
- CTSS | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 16/360 reads (4%) | called by muse, mutect2
- DACH1 | c.1241A>T p.H414L | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.056); called by muse, mutect2
- DNAH8 | c.1286T>C p.F429S | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAJC5G | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 17/341 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- EML6 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM155A | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.91); PolyPhen benign (0.014); called by muse, mutect2
- FPGT | c.1307G>C p.R436T | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.149); called by muse, mutect2
- GPATCH4 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- GRSF1 | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- HMCN1 | c.5501C>G p.S1834C | Missense Mutation (SNP) | VAF 25/538 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); called by muse, mutect2
- ICAM5 | c.1631G>A p.R544Q | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2
- ICE1 | c.3184G>A p.E1062K | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.098); called by muse, mutect2
- MLH1 | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 16/251 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- MRPS35 | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.042); called by muse, mutect2
- NCF2 | c.98A>T p.Q33L | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2
- OTUB2 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.564); called by muse, mutect2
- PHF11 | c.887T>G p.L296W | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- PREPL | c.119G>C p.R40T | Missense Mutation (SNP) | VAF 13/339 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.051); called by muse, mutect2
- RINT1 | c.1178A>G p.Y393C | Missense Mutation (SNP) | VAF 11/287 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RNF138 | c.152G>C p.G51A | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); called by muse, mutect2
- SLFN5 | c.715A>G p.I239V | Missense Mutation (SNP) | VAF 16/501 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.222); called by muse, mutect2
- SYT1 | c.516G>C p.L172F | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); called by muse, mutect2
- TCHHL1 | c.1657C>A p.L553M | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2
- TGS1 | c.772C>G p.Q258E | Missense Mutation (SNP) | VAF 10/305 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TLCD4 | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 12/354 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- TRDV1 | c.201C>G p.F67L | Missense Mutation (SNP) | VAF 10/291 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.056); called by muse, mutect2
- TSHZ2 | c.853G>C p.D285H | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TTN | c.97183G>C p.E32395Q (on ENST00000591111; = p.E24971Q on NM_003319.4) | Missense Mutation (SNP) | VAF 10/174 reads (6%) | PolyPhen benign (0.098); called by muse, mutect2
- TUBGCP3 | c.2389C>G p.L797V | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.052); called by muse, mutect2
- ZFHX4 | c.4940A>T p.Q1647L | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- EYS | c.5280A>G p.T1760= | Silent (SNP) | VAF 10/220 reads (5%) | catalogued as rs970771671; ClinVar: likely benign; called by muse, mutect2
- GK5 | c.1362G>C p.L454= | Silent (SNP) | VAF 10/292 reads (3%) | called by muse, mutect2
- HSPA6 | c.765G>C p.L255= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as COSV59061950; called by muse, varscan2
- MUC5B | c.4134C>T p.I1378= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs749634798, COSV101500089, COSV71592793; called by mutect2, varscan2
- MYH7 | c.1167G>A p.G389= | Silent (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- PCNT | c.2136G>A p.L712= | Silent (SNP) | VAF 11/133 reads (8%) | called by muse, mutect2
- SV2A | c.351G>A p.A117= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs200889129, COSV100975030; called by muse, mutect2, varscan2
- TMPRSS9 | c.2766G>C p.L922= (on ENST00000648592; = p.L888= on NM_182973.2) | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV53113645; called by muse, mutect2, varscan2
- BAK1 | c.351-293A>T | Intron (SNP) | VAF 9/211 reads (4%) | called by muse, mutect2
- CD3E | c.*38C>T | 3'UTR (SNP) | VAF 9/160 reads (6%) | called by muse, mutect2
- COP1 | c.2133+18426A>T | Intron (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- FBRS | chr16:30659941 C>T | 5'Flank (SNP) | VAF 5/93 reads (5%) | catalogued as rs1316442136; called by muse, mutect2
- MED14 | chrX:40735701 C>T | 5'Flank (SNP) | VAF 9/125 reads (7%) | called by muse, mutect2
- PASK | c.1307-43G>A | Intron (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- SSX6P | n.210C>A | RNA (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*1634G>C | 3'UTR (SNP) | VAF 13/324 reads (4%) | called by muse, mutect2
